Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A4QS, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A4QS-01A (Primary Tumor).

Gross Description: There is a part of the esophagus with part of the stomach. In the lower third of the esophagus there is an exophytic tumor up to 5 cm in size with invasion of all wall layers. In the adjacent fatty tissue there are metastatic lymph nodes up to 0.6 cm in size. Surgical margins and omentum are free of tumor growth.

Microscopic Description: Adenocarcinoma of the esophagus, G-3, with focal mucin production, invasion into the fatty tissue. There is a focal growth under the normal squamous epithelium. In the vessels there are tumor emboli. There are foci of perineural invasion. Six examined lymph nodes demonstrated metastases. Surgical margins are free of tumor growth.

Diagnosis Details: Tumor Features: Exophytic (polypoid), Tumor Extent: Adventitia, Venous Invasion: Present, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Thoracic esophagus

Tumor size: 0 x 0 x 5 cm

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Adventitia

Lymph nodes: 6/6 positive for metastasis (Paraesophageal lymph nodes 6/6)

Lymphatic invasion: Not specified

Venous invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3

Adenocarcinoma, NOS 8140/3

Path: Site: esophagus, thoracic C15.1

hw
10/23/12

Reviewed (initials):	DATE Reviewed: 10/15/12	

hw
10/23/12

Source: NCI Genomic Data Commons file 45349cc3-0f25-482b-a6f0-fabdbaad1279 (TCGA-IG-A4QS.A1C91436-4532-43B8-95A8-CF502CDD3285.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).